Gene-level copy-number profile of tumor specimen MP2PRT-PASBZW-TTP1-A from MP2PRT case MP2PRT-PASBZW, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 8.0 years (2,921 days).
Specimen MP2PRT-PASBZW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 16a37920-7ed7-4503-acda-5dd6b7a94527.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASBZW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/7a95c5be-6ba2-4592-b2fe-cc8cbfe3c3b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,232; copy number 2: 34,908; copy number 3: 18,296; copy number 4: 3,199; copy number 5: 542; copy number 6: 217.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr4:9,459,255–9,484,702, 2 genes: OR7E86P, OR7E85P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 759 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:113,696,831–113,759,489, 1 gene, copy number 5 (within-gene range 2–5): PHTF1.
- chr1:113,761,832–121,580,524, 179 genes, copy number 5 (broad region; genes not listed).
- chr12:43,353,866–48,351,414, 108 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:55,608,043–76,559,809, 471 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
